Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A4IS, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A4IS-01A (Primary Tumor).

Gross Description: Skin flap up to 6 x 4.5 cm in size, with brown spot up to 2.5 cm in its diameter.
Surgical margins are free of tumor growth.

Microscopic Description: Malignant melanoma of the skin with superficial ulceration. Breslow's depth -- 2.5 mm.

Diagnosis Details: Tumor Features: Pigmented, Tumor Extent: Tumor 2.01?4mm with or without ulceration, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, trunk

Tumor size: 0 x 0.25 x 2.5 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade:

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Breslow's depth -- 2.5 mm.

Comments: None

1CD-0-3

Melanoma, NOS 8720/3

Site: skin, trunk C44.5

pw
10/2/12

Case is (single):		

pw 9/25/12

Source: NCI Genomic Data Commons file c4e0b416-72fb-4660-a0bc-3e30aed775d2 (TCGA-EB-A4IS.5BFDB360-698E-40AB-A36A-09CD794C9BA7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).